Somatic mutation profile of tumor specimen 0DQSTV from CCDI case PBCFBC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 17.6 years (6,434 days).
Specimen 0DQSTV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1f0f4b0-53ce-4b65-b0f0-849c44ab2481.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQSUN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/023c63b5-c548-4da0-b4ab-8ce4db8cbb7c

The open-access MAF lists 41 somatic variants for this specimen: 25 protein-altering or splice-affecting, 9 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 9, Intron 4, Nonsense Mutation 2, 5'UTR 2, Frame Shift Del 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDC14C | c.579del p.I195Lfs*38 (on ENST00000428251; = p.I88Lfs*38 on NM_152627.3) | Frame Shift Del (DEL) | VAF 387/1571 reads (25%) | catalogued as rs1271346370; called by mutect2, pindel, varscan2
- ELOA2 | c.1630C>A p.L544I | Missense Mutation (SNP) | VAF 170/365 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV55295362, COSV55310392; called by muse, mutect2, varscan2
- KHNYN | c.1378C>T p.R460W | Missense Mutation (SNP) | VAF 102/461 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752220870, COSV99249670; called by muse, mutect2, varscan2
- NEB | c.16159G>A p.D5387N | Missense Mutation (SNP) | VAF 66/599 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs182252292; called by muse, mutect2, varscan2
- OCLN | c.1216G>A p.G406S | Missense Mutation (SNP) | VAF 18/650 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs539541122; called by muse, mutect2
- ST18 | c.2227C>T p.R743C | Missense Mutation (SNP) | VAF 134/307 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52496936; called by muse, mutect2, varscan2
- STARD7 | c.542A>G p.N181S | Missense Mutation (SNP) | VAF 165/379 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.391); catalogued as rs150385509; called by muse, mutect2, varscan2
- TENM3 | c.6521G>A p.R2174H | Missense Mutation (SNP) | VAF 66/916 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs751169755, COSV69300050; called by muse, mutect2
- TET2 | c.2539C>T p.Q847* | Nonsense Mutation (SNP) | VAF 358/1024 reads (35%) | catalogued as rs770247649, COSV99481951; called by muse, mutect2, varscan2
- TRPM6 | c.1254G>C p.W418C | Missense Mutation (SNP) | VAF 257/473 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1414203976; called by muse, mutect2, varscan2
- UGT2A3 | c.1129G>T p.G377W | Missense Mutation (SNP) | VAF 466/854 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52361501; called by mutect2, varscan2
- ARHGAP44 | c.506T>A p.L169* | Nonsense Mutation (SNP) | VAF 320/350 reads (91%) | called by mutect2, varscan2
- C9 | c.877A>T p.M293L | Missense Mutation (SNP) | VAF 270/576 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CASD1 | c.453G>T p.W151C | Missense Mutation (SNP) | VAF 28/734 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CPN2 | c.1386C>G p.S462R | Missense Mutation (SNP) | VAF 66/950 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FAT3 | c.2834T>A p.V945D | Missense Mutation (SNP) | VAF 326/761 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- FCER2 | c.815T>A p.F272Y | Missense Mutation (SNP) | VAF 166/324 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRIA1 | c.2335A>C p.K779Q | Missense Mutation (SNP) | VAF 215/482 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- MX2 | c.1632C>A p.N544K | Missense Mutation (SNP) | VAF 43/838 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PAX3 | c.958+1G>T p.X320_splice | Splice Site (SNP) | VAF 380/861 reads (44%) | called by muse, mutect2, varscan2
- PCCB | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 125/493 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- RASGRP4 | c.1483_1484del p.S495Gfs*50 | Frame Shift Del (DEL) | VAF 161/501 reads (32%) | called by pindel, varscan2
- TCAF2 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 86/200 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- TMPRSS6 | c.715C>T p.H239Y | Missense Mutation (SNP) | VAF 242/651 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.593); called by muse, mutect2
- VSIG4 | c.731C>A p.P244H | Missense Mutation (SNP) | VAF 231/261 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- ALOXE3 | c.1014C>T p.C338= | Silent (SNP) | VAF 25/355 reads (7%) | called by muse, mutect2
- CNTNAP1 | c.3651C>T p.N1217= | Silent (SNP) | VAF 124/563 reads (22%) | catalogued as rs747462502; called by muse, mutect2, varscan2
- CPNE1 | c.711C>G p.V237= (on ENST00000352393; = p.V242= on NM_003915.5) | Silent (SNP) | VAF 62/852 reads (7%) | called by muse, mutect2
- DMRTA2 | c.231C>T p.G77= | Silent (SNP) | VAF 98/1258 reads (8%) | called by muse, mutect2
- HMCN1 | c.11412A>T p.P3804= | Silent (SNP) | VAF 221/372 reads (59%) | called by muse, mutect2, varscan2
- ILDR1 | c.1221G>A p.R407= (on ENST00000344209 / NM_001199799.2; = p.R363= on NM_175924.4) | Silent (SNP) | VAF 122/479 reads (25%) | called by muse, mutect2, varscan2
- MEF2C | c.615G>A p.T205= | Silent (SNP) | VAF 154/377 reads (41%) | catalogued as rs776496777; ClinVar: likely benign; called by muse, mutect2, varscan2
- SH2B1 | c.960C>T p.S320= | Silent (SNP) | VAF 308/785 reads (39%) | called by muse, mutect2, varscan2
- SPAM1 | c.1407A>G p.L469= | Silent (SNP) | VAF 42/1140 reads (4%) | called by muse, mutect2
- AL450344.3 | chr6:150600015 C>G | 5'Flank (SNP) | VAF 210/244 reads (86%) | called by muse, mutect2, varscan2
- ALG6 | c.82+100A>G | Intron (SNP) | VAF 54/168 reads (32%) | called by muse, mutect2, varscan2
- ARID1B | c.2986+69G>T | Intron (SNP) | VAF 23/157 reads (15%) | called by muse, mutect2, varscan2
- JARID2 | c.-18C>A | 5'UTR (SNP) | VAF 98/236 reads (42%) | called by muse, mutect2, varscan2
- LCN2 | c.276-100G>A | Intron (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- MASP1 | c.1303+5668G>A | Intron (SNP) | VAF 225/512 reads (44%) | called by muse, mutect2, varscan2
- PRR15 | c.-54G>A | 5'UTR (SNP) | VAF 119/301 reads (40%) | called by muse, mutect2, varscan2
